TARGET case TARGET-40-NAAGZW — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of other and unspecified sites. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a5aed135-fa67-580d-b70c-b21fd2a061ae

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 22 years; Vital status: Alive.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C41.9; Tissue or organ of origin: Bone, NOS; Classification of tumor: primary; Age at diagnosis: 22.8 years (8,312 days); Year of diagnosis: 2009; Days to last follow up: 2,149 days (5.9 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 2,149.

Biospecimens (1 sample)
- Sample TARGET-40-NAAGZW-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_20230709.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 2149
- Specific tumor site: Bone NOS

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-NAAGZW-06A-01:
- Specimen Type: frozen solid tumor
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 60
- % Non Tumor Nuclei: Top from Biopsy: 40
- % Cellular Tumor: Top from Biopsy: 5
- % Normal: Top from Biopsy: 40
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 55
- % Tumor Nuclei: Bottom from Biopsy: 50
- % Non Tumor Nuclei: Bottom from Biopsy: 50
- % Cellular Tumor: Bottom from Biopsy: 5
- % Normal: Bottom from Biopsy: 7
- % Stroma: Bottom from Biopsy: 0
- % Necrosis: Bottom from Biopsy: 88
- PASS/FAIL: fail (>50%NC)
